Somatic mutation profile of tumor specimen TCGA-HW-A5KM-01A (aliquot TCGA-HW-A5KM-01A-11D-A27K-08) from TCGA case TCGA-HW-A5KM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.2 years (12,845 days).
Specimen TCGA-HW-A5KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45321714-b409-4b8a-bf49-0032ca6a8f4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-A5KM-10A (Blood Derived Normal), aliquot TCGA-HW-A5KM-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c1d21b5-e144-4d05-8a78-bbde38b25898

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, In Frame Del 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 33/44 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.3051_3084del p.E1017Dfs*5 | Frame Shift Del (DEL) | VAF 34/46 reads (74%) | catalogued as COSV64880087; called by mutect2, pindel
- COQ8A | c.1573A>G p.I525V | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV62017138; called by muse, mutect2
- DPY19L2 | c.1190A>C p.Y397S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1469096011, COSV100116902; called by muse, mutect2, varscan2
- FIZ1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55607845; called by muse, mutect2, varscan2
- LAMB4 | c.3866T>C p.L1289P | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52726611; called by muse, mutect2, varscan2
- SLC6A5 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54230424; called by muse, mutect2, varscan2
- SYCP1 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65699995; called by muse, mutect2, varscan2
- TADA1 | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV63310480; called by muse, mutect2, varscan2
- ZNF169 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747977860, COSV61764859; called by muse, mutect2, varscan2
- FMNL1 | c.3154_3156del p.K1052del | In Frame Del (DEL) | VAF 56/170 reads (33%) | called by mutect2, pindel, varscan2
- IFRD1 | c.1247_1249del p.K416del | In Frame Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- TPTE | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ABCC4 | c.1314C>T p.G438= | Silent (SNP) | VAF 57/159 reads (36%) | catalogued as rs150945397; called by muse, mutect2, varscan2
- TIGIT | c.75C>G p.G25= | Silent (SNP) | VAF 87/298 reads (29%) | catalogued as COSV67329245; called by muse, mutect2, varscan2
- POLR3D | chr8:22245028 C>G | 5'Flank (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
